Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A615, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A615-01A (Primary Tumor).

Tumor ID

ICD-0-3
Oligodendroglioma NOS
9450/3
Site CCBF Supratentorial NOS
C71.0
path Brain, temporal lobe
C71.2
QW 4/16/13

Microscopic Description:

Sections demonstrate a variably cellular glioma that diffusely infiltrates both the gray and white matter. The majority of the tumor cells demonstrate prominent perinuclear halos. They consistently have round to oval nuclei. Atypia is moderate. Cellularity is accentuated in a multinodular pattern. Neither microvascular proliferation nor necrosis are identified. A few scattered mitotic figures are seen, but these are insufficient by themselves to warrant classification as anaplastic.

Scattered MIB-1 reactive cells are present throughout the tumor. However, even in the most proliferative regions, a labeling index of only 2.2% is calculated. Combined with the other histologic features, this does not warrant classification as anaplastic/grade III. Nevertheless, the cluster of hypercellularity and degree of atypia is somewhat worrisome and close follow up is indicated.

Diagnosis:

Left Temporal Tumor

Oligodendroglioma, Grade II

MIB-1 Labeling Index= 2.2%

Site	CCBF	Yes	No

Source: NCI Genomic Data Commons file 0f58d5ef-5bd5-407b-a468-b2a0bdb5d59b (TCGA-HT-A615.34BD1967-CF9D-4B21-866A-BB100739E1C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).